Somatic mutation profile of tumor specimen TCGA-AB-2822-03D (aliquot TCGA-AB-2822-03D-01W-0755-09) from TCGA case TCGA-AB-2822, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.8 years (24,017 days).
Specimen TCGA-AB-2822-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d8b38b6-2167-4da5-b14c-6b04bcd4d741.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2822-11D (Solid Tissue Normal), aliquot TCGA-AB-2822-11D-01W-0755-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2022838-46f6-4d54-a693-99f335e52378

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 5'Flank 1, Splice Site 1, Frame Shift Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGXT2 | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99183791; called by muse, mutect2, varscan2
- DNMT3A | c.1668-1G>A p.X556_splice | Splice Site (SNP) | VAF 9/15 reads (60%) | catalogued as COSV99263411; called by muse, mutect2, varscan2
- GCM2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780594439, CM099924, COSV65276268, COSV65276393; called by muse, mutect2, varscan2
- GRID1 | c.2225A>T p.D742V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025221; called by muse, mutect2, varscan2
- LEO1 | c.1971C>G p.I657M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100166597; called by muse, mutect2, varscan2
- LRRC43 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs773915313, COSV60288994; called by muse, mutect2, varscan2
- MED12 | c.5063G>A p.W1688* | Nonsense Mutation (SNP) | VAF 33/34 reads (97%) | catalogued as COSV100379026; called by muse, mutect2, varscan2
- SMC1A | c.1460C>G p.A487G | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100447552; called by muse, mutect2, varscan2
- SYT17 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100810802; called by muse, varscan2
- TET2 | c.945del p.Q317Rfs*30 | Frame Shift Del (DEL) | VAF 118/264 reads (45%) | catalogued as COSV99484131; called by mutect2, varscan2
- TMEM200A | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs149308469, COSV51656363; called by muse, mutect2, varscan2
- TMEM231 | c.617A>G p.Y206C (on ENST00000258173 / NM_001077418.3; = p.Y235C on NM_001077416.2) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs374279951; called by muse, mutect2, varscan2
- WRN | c.3513G>A p.M1171I | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV99989478; called by muse, mutect2, varscan2
- WSCD1 | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780496682, COSV100496693; called by muse, mutect2, varscan2
- EDIL3 | c.612G>A p.A204= | Silent (SNP) | VAF 36/241 reads (15%) | catalogued as rs757759194, COSV99677957; called by muse, mutect2, varscan2
- ITPR3 | c.6801G>A p.A2267= | Silent (SNP) | VAF 77/164 reads (47%) | catalogued as rs761992573, COSV65414708; called by muse, mutect2, varscan2
- NCAPG | c.747C>T p.L249= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs968856880, COSV52270838; called by muse, mutect2, varscan2
- C3P1 | n.2444C>T | RNA (SNP) | VAF 168/409 reads (41%) | called by muse, mutect2, varscan2
- UTS2 | chr1:7853420 G>A | 5'Flank (SNP) | VAF 47/116 reads (41%) | catalogued as rs147322701; called by muse, mutect2, varscan2
